Surgical pathology report (de-identified scan), TCGA case TCGA-31-1944, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Imperial College, specimen TCGA-31-1944-01A (Primary Tumor).

[page 1 of 5]
Specimen Type:

- 1: RIGHT OVARY, TUBE
- 2: LEFT OVARY, TUBE
- 3: UTERUS, CERVIX, OMENTUM
- 4: SMALL BOWEL
- 5: RIGHT EXTERNAL ILIAC
- 6: RIGHT OBTURATOR
- 7: RIGHT INTERNAL ILIAC
- 8: RIGHT OBTURATOR
- 9: RIGHT PRESACRAL NODE
- 10: PARA-AORTIC NODE
- 11: DOUGHNUT
- 12: RIGHT PARA-AORTIC NODE

TCGA-31-1944

Clinical Details:

Bilateral adnexal masses and pelvic and para-aortic lymphadenopathy. Ca 125 –126.

Macroscopic Description:

1) RIGHT OVARY AND TUBE FOR FROZEN SECTION

Specimen of ovary with corresponding tube. The ovary measures 4 x 3 x 1.5 cm. There is a defect in the capsule, 1 cm in diameter. The cut surface of the ovary is solid with focal oedematous areas. The corresponding tube measures 4 cm in length and 0.5 cm in diameter. The serosal surface with the tube shows a deposit of tumour, 2 x 0.5 cm in maximum dimension. A small nodule is noted in the rod ligament 0.5 cm in diameter. Rep. sections taken.

BLOCKS: FS1A and FS1B – 1 pc in each
ROTA1 – Tube with implants on peritoneum surface, 2 pcs
ROT1B – 2 pcs, ? areas of capsule reach
ROT1C to ROT1H – Tumour, 1 pc in each

[page 2 of 5]
2) LEFT OVARY AND TUBE

The specimen comprises of ovary with corresponding tube, collectively weighing 25.6 grams. The ovary measures 7.5 x 3 x 1.5 cm. The capsule of the surface is smooth. No breach in the capsule is identified. An area of breach in the capsule measuring 0.8 cm is identified at one area. Rep. sections taken.

BLOCKS: A to D – Sections with breach in the capsule, 1 pc in each [REDACTED] TCGA-31-1944
E to M – Tumour, 1 pc in each
N – 2 pcs. [REDACTED]

3) OMENTUM, PLUS UTERUS AND CERVIX

Uterus with attached cervix weighing 285 g and a portion of omentum measuring 28 x 13 x 0.2 cm. The cervix measures 5 cm across, 2 cm anterior to posterior and 3 cm in length. It has a transverse os 0.2 cm. The cervical is 12 cm, transverse diameter of uterus 6.5 cm and anteroposterior diameter of uterus 5.5 cm. On opening the uterus the endometrium has a maximum thickness of 0.3 cm and the myometrium 2 cm. No tumour deposits are seen. Right parametrium and paracervical tissue are inked green. The left parametrium and paracervical tissue are inked blue. Fatty tissue contains no focal lesions or tumour deposits.

BLOCKS: A – anterior cervix, 1 pc.
B – posterior cervix, 1 pc.
C – lower uterine segment, 1 pc.
D – right parametrium, 1 pc.
E – left parametrium, 1 pc.
F – posterior serosal surface of cervix, 1 pc.
G – endometrium and myometrium, 1 pc.
H – endometrium, 1 pc.
J – endometrium and myometrium, 1 pc.
K – posterior serosal surface of uterus, 1 pc.
L and M – omentum, 1 pc. in each. [REDACTED]

4) SMALL BOWEL

A segment of bowel with peritoneum reflection measuring 7.5 cm in length and 2 cm in diameter. There is a defect 1.8 x 1.5 cm, posteriorly within the peritoneum reflection. The mucosal surface of the loop is unremarkable. The soft tissue resection margins are 4 cm proximally and 1 cm distally.

BLOCKS: A – Proximal resection margin, 2 pcs
B to D – Resection margin, 1 pc in each
E to G – 1 slice with defect in the posterior peritoneum reflection
H to J – Sections of tumour, 1 pc in each
L – Lymph nodes, 4 pcs
M – Lymph nodes, 2 pcs
N – High tie vessel, 1 pc

5) RIGHT EXTERNAL ILIAC NODE

Fibro-fatty tissue and lymph nodes collectively weighing 8.9 grams. Two enlarged lymph nodes are identified, each measuring 2 x 1 x 0.5 cm.

BLOCKS: A – 1 lymph node, 1 pc

[page 3 of 5]
B – 1 lymph node, 1 pc
C – Fibro-fatty tissue, multiple pcs.

6) RIGHT OBTURATOR

Fibro-fatty tissue, 4 x 1 x 1 cm, and weighing 6.8 grams. Multiple matted lymph nodes are identified.

BLOCKS: A – Matted lymph node, 1 pc
B – Fibro-fatty tissue, 1 pc

TCGA-31-1944

7) LEFT INTERNAL ILIAC

Enlarged lymph nodes and fibro-fatty tissue, 3 grams, and measuring 2.5 x 1 x 0.5 cm.

BLOCK: 1 – 1 lymph node, 1 pc.

8) LEFT OBTURATOR

Enlarged lymph nodes, weighing 6 grams, and measuring 2 x 1.5 x 1.5 cm.

BLOCKS: A and B – Sections of the same lymph node, 1 pc in each.

9) RIGHT PRESACRAL NODE

Two enlarged lymph nodes, collectively weighing 4 grams. The larger measures 2.5 x 0.5 x 0.5 cm and the smaller measures 1.5 x 1 x 0.5 cm.

BLOCKS: A and B – 1 lymph node each, 1 pc in each.

10) LEFT PARA-AORTIC NODE

Fibro-fatty tissue and lymph nodes, weighing 10 grams. Multiple matted enlarged lymph nodes are identified. 5 other lymph nodes are identified besides the matted group.

BLOCKS: A and B – 1 pc in each
C – 2 lymph nodes, 2 pcs
D – 3 lymph nodes, 3 pcs.

11) DOUGHNUT

The pot contains two doughnuts, one free-lying within the pot. The doughnut which was free-lying within the pot measures 1.5 cm in diameter. No focal lesions are identified. The other doughnut measures 1.5 cm in diameter. No focal lesions are identified.

BLOCKS: A and B – Free-lying doughnuts, A-2pcs, B-1pc.
C – Other doughnut, 2 pcs.

12) RIGHT PARA-AORTIC LYMPH NODE

Fibro-collagenous tissue collectively weighing 6 grams, and measuring 9 x 1 x 1 cm. 14 lymph nodes identified. The largest measures 2 cm.

BLOCKS: A – Largest lymph node, bisected, 2pcs
B to E – 4 lymph nodes in each block, 4 pcs in each
F – Fibro-fatty tissue. Multiple pcs.

Frozen Section Diagnosis:

FSA: Poorly differentiated malignant tumour

[page 4 of 5]
FSB: Poorly differentiated malignant tumour (peritoneal surface of the fallopian tube) with psammoma bodies. [REDACTED]

TCGA-31-1944 [REDACTED]

Microscopic Description:

- 1-2) A poorly differentiated serous papillary adenocarcinoma forming solid nests, but apparently arising from a pre-existing cyst partially lined by a single layer of atypical epithelium. The tumour has breached both ovaries onto the peritoneal surface. Tumour involves the right fallopian tube. The left fallopian tube is free of tumour. Vascular invasion is seen.
The tumour cells express ER, PgR(35%), WT1, mutant P53 and Ck7. Proliferation index as estimated by Ki67 expression is 78%.
- 1-3) All sections from cervix and uterine wall show diffuse vascular permeation by the serosal surface but it also reaches the endometrium. The endometrial glands not replaced by tumour are inactive.
The omentum does not contain tumour.
- 4) The serosa and subserosal tissue are extensively involved by metastatic poorly differentiated serous adenocarcinoma which is invading into the muscular layer of the small bowel.
Foci of tumour cells are seen in the submucosa (H4).
The intestinal mucosa is not reached.
Lymphatic neoplastic emboli are seen. Tumour deposits are noted in 5/7 lymph nodes identified. The small bowel resection margins show tumour involvement in the serosa.

[REDACTED]

Metastatic poorly differentiated serous adenocarcinoma is seen in 2/2 right external iliac nodes (N.5), in 1/2 right obturator lymph nodes (N.6), in 2/2 left internal iliac (N.7), in 6/6 left obturator lymph nodes (N.8), in 2/2 right presarosal nodes (N9.), in 8/18 left para-aortic nodes (N.10) and 10/30 right para-aortic lymph nodes (N.12).

- 11) Sections of large bowel mucosa with no evidence of metastatic tumour.

Final Diagnosis:

OVARIES, TUBES, LYMPH NODES, SMALL BOWEL, UTERUS: BILATERAL OVARIAN POORLY DIFFERENTIATED SEROUS PAPILLARY ADENOCARCINOMA INVOLVING RIGHT FALLOPIAN TUBES, THE WALL OF THE SMALL BOWEL, REGIONAL LYMPH NODES, CERVIX AND UTERUS (stage IIIc).

Additional Pathologist(s)/BMS(s)
[REDACTED]

[page 5 of 5]
Date Complete:
Date Reported:

Addendum Diagnosis

Immunohistochemistry was performed and shows moderate ER staining in 75% of tumour cells, and moderate PgR staining in 5% of tumour cells.

Addendum Comment

{Not Entered}

TCGA-31-1944

Source: NCI Genomic Data Commons file 41da970d-fa1f-4b15-bad4-848c00bdfaee (TCGA-31-1944.BD7361F7-07C1-4BE8-92C6-4F0A3DEA99B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).